Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A884, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A884-01A (Primary Tumor).

[page 1 of 2]
Accession:
Specimen Date/Time:

DIAGNOSIS

- (A) LEFT GLOBE, ENUCLEATION: (61-90%) (1-30%)
UVEAL MELANOMA, MIXED EPITHELIOID AND SPINDLED TYPES, approximately 20 mm base x 10 mm height.
TUMOR INVOLVING CHOROID AND CILIARY BODY WITH FOCAL EXTENSION ONTO IRIS.
CHOROIDAL INVASION PRESENT.
No unequivocal involvement of canal of schlemm, see comment.
Optic nerve negative for tumor.
Vortex veins negative for tumor.
Mitoses are 5 per 10 HPF.
- ICD-O-3
Melanoma, epithelioid & spindle
cell mixed 8770/3
- (B) LEFT EYE FNA, BIOPSY:
Sample for send out testing only, See comment.
- Site: Overlapping lesion Deep &
Adnexa 0698 2/11/14

COMMENT

The tumor approximates the canal of schlemm with inflammation present without definitive invasion by tumor. Levels examir
Background changes also noted include degeneration of the retina and lens with background hyperplasia of retinal epitheliur

The specimen for part B was sent to for further diagnostic testing ordered by , which will b
reported separately within the scan documents of

GROSS DESCRIPTION

(A) LEFT GLOBE - A left intact enucleation specimen (21 x 21 x 23 cm) has an attached 13 mm optic nerve. The cornea is
10 mm with a distorted gray iris and pupil (0.7 x 0.4 cm) irregular opening. Transillumination shows a shadow approximately
o'clock extending from near the limbus to 5 mm from the optic nerve approximately 22 x 20 mm base. Tissue is harvested p
protocol. The vitreous is tinged yellow. The tumor is multinodular, variegated from light tan to gray with a height up to 10 mm
The tumor grossly extends to the ciliary body and is partially polypoid. The lens has disintegrated and is edematous, pale
translucent white, occupying the anterior aspect of the specimen.

SECTION CODE: A1, vortex veins; A2, optic nerve margin; A3, focal tumor with harvest calotte; A4, opposite calott
tumor; A5, pupil optic-nerve section with tumor.

(B) LEFT EYE FNA BIOPSY, NOT FOR PERMANENT AND SHIPPED VIA START IMMEDIATE -80 CENTIGRADE -
Multiple tan and clear tissue with mucoid material (0.4 x 0.4 x 0.3 cm). For gross ID only. Specimen is sent out via

BIOMARKER TESTING

The following material is selected for biomarker testing:

Primary Tumor Block: A4

CLINICAL HISTORY

Uveal melanoma.

SNOMED CODES

T-AA000, M-82703

"Some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have no

[page 2 of 2]
Page: 2

Accession:
Specimen Date/Time:

-----END OF REPORT-----

Diagnostic Screening		☒
IPAX Discrepancy		☒
2 or More History		☒
Study System or Pathology		☒
Case (C) (P) (S) / DISQUALIFIED		

Source: NCI Genomic Data Commons file 15746bb8-744e-4733-ba8b-58e79fc04496 (TCGA-WC-A884.21C6D225-052E-4E12-A639-A1B671E22CE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).